Somatic mutation profile of tumor specimen TCGA-AA-3684-01A (aliquot TCGA-AA-3684-01A-02W-0900-09) from TCGA case TCGA-AA-3684, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.0 years (23,741 days).
Specimen TCGA-AA-3684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07124f8b-acdb-4305-a023-25e642e38be9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3684-10A (Blood Derived Normal), aliquot TCGA-AA-3684-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d51b95fb-0ac6-447d-81be-6ab4a10e3dfd

The open-access MAF lists 139 somatic variants for this specimen: 106 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 31, Nonsense Mutation 12, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 1, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 29/225 reads (13%) | catalogued as rs1254176854, CM106359, COSV57331724, COSV57359899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 178/504 reads (35%) | hotspot (GDC flag); catalogued as COSV55455231; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- AKAP9 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 58/218 reads (27%) | catalogued as rs779398715, COSV62339967; called by muse, mutect2, varscan2
- ANK2 | c.4252C>T p.R1418C | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749093363, COSV52181451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.5233C>T p.P1745S | Missense Mutation (SNP) | VAF 162/1062 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.153); catalogued as COSV52194351; called by muse, mutect2, varscan2
- AQR | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.13); catalogued as COSV50061127; called by muse, mutect2, varscan2
- ATP10A | c.4125G>A p.M1375I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV63526538; called by muse, mutect2, varscan2
- ATRN | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV53535878; called by muse, mutect2, varscan2
- BAAT | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52291427; called by muse, mutect2, varscan2
- C3orf20 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as rs780464445, COSV53790413; called by muse, mutect2, varscan2
- CACNA1E | c.425A>C p.K142T | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701256; called by muse, mutect2
- CACNA2D1 | c.1182T>A p.Y394* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV62395991; called by muse, mutect2, varscan2
- CASR | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs749288251, CM123744, COSV56138879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP128 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV55367184, COSV99823491; called by muse, mutect2
- CEP290 | c.3893T>A p.L1298H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV58357737; called by muse, mutect2, varscan2
- CHRM2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs1409906654, COSV57768248; called by muse, mutect2, varscan2
- CNNM1 | c.1760A>C p.K587T | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV63203948; called by muse, mutect2, varscan2
- CNPY2 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV56265449; called by muse, mutect2, varscan2
- CUBN | c.9646C>T p.L3216F | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.299); catalogued as COSV64728494, COSV64729875; called by muse, mutect2, varscan2
- DCTPP1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747527404, COSV60000651, COSV60001005; called by muse, mutect2, varscan2
- DIP2B | c.4262G>A p.R1421H | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as rs765219401, COSV56593945; called by muse, mutect2, varscan2
- DMRTA1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs148996315; called by muse, mutect2, varscan2
- DNAH2 | c.3572C>G p.A1191G | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV101208986, COSV66728912; called by muse, mutect2, varscan2
- DNPEP | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs372081874; called by muse, varscan2
- DUOX2 | c.3163G>A p.V1055M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs367803824, COSV66530997; called by muse, varscan2
- ELAPOR2 | c.1828G>A p.G610S (on ENST00000450689 / NM_001142749.3; = p.G443S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.095); catalogued as rs778431064, COSV51888589; called by muse, mutect2, varscan2
- EMCN | c.687T>A p.D229E | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as COSV56465558; called by muse, mutect2, varscan2
- EPG5 | c.7442+1G>T p.X2481_splice | Splice Site (SNP) | VAF 10/204 reads (5%) | catalogued as COSV99956372; called by muse, mutect2
- FAM149A | c.2095C>T p.R699* (on ENST00000356371 / NM_001367768.2; = p.R408* on NM_015398.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as rs766661467, COSV57030946; called by muse, mutect2, varscan2
- FAM184A | c.3033+2T>C p.X1011_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100137305; called by muse, mutect2, varscan2
- FBXL7 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as COSV100310578, COSV61654862; called by muse, mutect2, varscan2
- FILIP1 | c.3038C>G p.S1013C | Missense Mutation (SNP) | VAF 36/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV52743155; called by muse, mutect2
- FSTL5 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.219); catalogued as rs377562641, COSV60237988; called by muse, mutect2
- GAPVD1 | c.2028T>G p.I676M | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV99782565; called by muse, mutect2
- GJA9 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV62532996; called by muse, mutect2, varscan2
- GPC6 | c.1502G>T p.C501F | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs746531582, COSV65543274; called by muse, mutect2, varscan2
- GPR87 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV53464808; called by muse, mutect2, varscan2
- GTF3C5 | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | catalogued as COSV59602360; called by muse, mutect2
- HAUS6 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs761183330, COSV65841006; called by muse, mutect2, varscan2
- IGHD | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.041); catalogued as COSV101162786; called by muse, mutect2, varscan2
- ITGB4 | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs751047725, COSV52334506; called by muse, mutect2, varscan2
- ITIH2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs201601009, COSV64434194; called by muse, mutect2, varscan2
- ITPKB | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs755294781, COSV55271499; called by muse, mutect2
- KCND3 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56175499; called by muse, mutect2, varscan2
- LRBA | c.6225C>T p.A2075= | Splice Region (SNP) | VAF 20/136 reads (15%) | catalogued as rs201176491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.13717C>T p.R4573* | Nonsense Mutation (SNP) | VAF 23/164 reads (14%) | catalogued as rs760776195, COSV67186046; called by muse, mutect2, varscan2
- LRP1B | c.11347C>T p.R3783* | Nonsense Mutation (SNP) | VAF 27/188 reads (14%) | catalogued as rs755519211, COSV101260873, COSV67219306; called by muse, mutect2, varscan2
- MAPKBP1 | c.2228G>A p.R743H (on ENST00000456763 / NM_001128608.2; = p.R737H on NM_014994.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs534654016, COSV52958394; called by muse, mutect2
- MEST | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs756420254, COSV56230243; called by muse, mutect2, varscan2
- MXRA5 | c.3026T>G p.V1009G | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99475533; called by muse, mutect2
- MXRA5 | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV99475535; called by muse, mutect2
- MYO16 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 44/210 reads (21%) | catalogued as COSV51823032; called by muse, mutect2, varscan2
- NEIL3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1419494369, COSV52813309; called by muse, mutect2, varscan2
- NET1 | c.1665A>T p.R555S (on ENST00000355029 / NM_001047160.3; = p.R501S on NM_005863.5) | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); catalogued as rs763143040, COSV61793188; called by muse, mutect2, varscan2
- NLRP4 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs370476091, COSV56708371; called by muse, mutect2, varscan2
- NRAP | c.4061A>G p.Q1354R (on ENST00000359988 / NM_001322945.2; = p.Q1319R on NM_006175.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63494760; called by muse, mutect2, varscan2
- OGA | c.2537A>G p.D846G | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs1045034877, COSV63383773; called by muse, mutect2, varscan2
- OR52K1 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.446); catalogued as COSV56905070; called by muse, mutect2, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- PAGE2 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 36/403 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV66596259; called by muse, mutect2
- PDS5B | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs369886085; called by muse, mutect2, varscan2
- PDZD2 | c.5266A>G p.S1756G | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs775958096, COSV56861717; called by muse, mutect2, varscan2
- PDZRN4 | c.2816G>A p.R939H (on ENST00000402685 / NM_001164595.2; = p.R681H on NM_013377.4) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755141579, COSV54193075; called by muse, mutect2, varscan2
- PKIA | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 68/365 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV61917418; called by muse, mutect2, varscan2
- PLSCR4 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs1265727887, COSV61609320; called by muse, mutect2, varscan2
- PRPS2 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV66126719; called by muse, mutect2, varscan2
- PTPRK | c.2194G>C p.A732P | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV63909509; called by muse, mutect2, varscan2
- PXDN | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs748030944, COSV53248532; called by muse, mutect2, varscan2
- RAD23B | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1184982125, COSV63660875; called by muse, mutect2
- RBBP6 | c.5279G>A p.S1760N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.051); catalogued as COSV60509223; called by muse, mutect2
- RBM5 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); catalogued as COSV61739386; called by muse, mutect2, varscan2
- RCOR3 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65367188; called by muse, mutect2, varscan2
- RNF103 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 28/892 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV99409895; called by muse, mutect2
- ROCK2 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 34/626 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55086268; called by muse, mutect2
- SCN5A | c.5738G>A p.R1913H (on ENST00000333535 / NM_198056.3; = p.R1912H on NM_000335.5) | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199473327, CM057206, COSV61143523; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SLC32A1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV54147153; called by muse, mutect2, varscan2
- SLFN5 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs755208700, COSV55484290; called by muse, mutect2, varscan2
- SOX9 | c.1302del p.I435Sfs*35 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as COSV55428229; called by mutect2, pindel, varscan2
- SPATA5L1 | c.1944C>G p.I648M | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV99972781; called by muse, mutect2
- SPEM2 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV60368040; called by muse, mutect2
- STON1-GTF2A1L | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.332); catalogued as rs1558770293, COSV59140011; called by muse, mutect2, varscan2
- TAF6L | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as rs759238822, COSV53667604; called by muse, mutect2, varscan2
- TCHH | c.4850G>A p.R1617H | Missense Mutation (SNP) | VAF 75/438 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs370364413; called by muse, mutect2, varscan2
- TFDP3 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59538956; called by muse, mutect2, varscan2
- TMED2 | c.319A>T p.M107L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV51630378; called by muse, mutect2, varscan2
- TNKS2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs747895530, COSV100861103, COSV65414959; called by muse, mutect2, varscan2
- TSHZ2 | c.1197G>A p.M399I | Missense Mutation (SNP) | VAF 29/684 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100295259; called by muse, mutect2
- TTN | c.89461C>T p.P29821S (on ENST00000591111; = p.P22397S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/503 reads (4%) | PolyPhen benign (0.046); catalogued as COSV60189201; called by muse, mutect2
- TUBB4A | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51170637; called by muse, varscan2
- VCAM1 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs769528923, COSV54118516; called by muse, mutect2, varscan2
- XPR1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222128792, COSV62561333; called by muse, mutect2, varscan2
- ZIC4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 28/153 reads (18%) | catalogued as rs201698839; called by muse, mutect2, varscan2
- ZIK1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs368879763; called by muse, mutect2, varscan2
- ZNF114 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 32/201 reads (16%) | catalogued as COSV59945543; called by muse, mutect2, varscan2
- ZNF208 | c.2073A>C p.K691N | Missense Mutation (SNP) | VAF 84/604 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV68114000; called by muse, varscan2
- ZNF512B | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99411167; called by muse, mutect2
- ZNF560 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 73/427 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56872650; called by muse, mutect2, varscan2
- ZRANB2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs977813121, COSV54672530; called by muse, mutect2, varscan2
- APC | c.4393_4394dup p.S1465Rfs*9 | Frame Shift Ins (INS) | VAF 54/245 reads (22%) | called by mutect2, varscan2
- COL19A1 | c.2417dup p.G807Wfs*14 | Frame Shift Ins (INS) | VAF 53/185 reads (29%) | called by mutect2, pindel, varscan2
- KCNE3 | c.75del p.H26Tfs*45 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- PIK3C2G | c.3634_3642del p.N1212_I1214del (on ENST00000676171; = p.N1171_I1173del on NM_004570.5) | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- POLN | c.1868-3_1868-2del p.X623_splice | Splice Site (DEL) | VAF 10/69 reads (14%) | called by pindel, varscan2
- TAS2R42 | c.363_366del p.W121* | Frame Shift Del (DEL) | VAF 39/218 reads (18%) | called by mutect2, pindel, varscan2
- A4GALT | c.525C>T p.S175= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs201965177, COSV50747190; called by muse, mutect2, varscan2
- ACVR2B | c.403C>T p.L135= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV61704166; called by muse, mutect2, varscan2
- BAG3 | c.1530C>G p.L510= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as COSV64842837; called by muse, mutect2
- BCL7A | c.156G>A p.T52= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs768322076, COSV55852747, COSV99946740; called by muse, mutect2, varscan2
- C10orf71 | c.1515C>T p.D505= | Silent (SNP) | VAF 37/244 reads (15%) | catalogued as rs770842902, COSV60514817; called by muse, mutect2, varscan2
- CCDC88C | c.2142G>A p.E714= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV101105360, COSV66242717; called by muse, mutect2, varscan2
- CP | c.2067T>G p.P689= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV52834169, COSV52835046; called by muse, mutect2, varscan2
- CPD | c.3993G>A p.K1331= | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as COSV56717094; called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- DPH2 | c.1443C>T p.I481= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs775199490, COSV52545657; called by muse, mutect2, varscan2
- GALNT17 | c.486C>T p.N162= | Silent (SNP) | VAF 46/181 reads (25%) | catalogued as rs368749036; called by muse, mutect2, varscan2
- GIGYF2 | c.498C>T p.D166= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1276980199, COSV65254210; called by muse, mutect2, varscan2
- GRIK1 | c.345C>T p.S115= | Silent (SNP) | VAF 32/194 reads (16%) | catalogued as rs772362200, COSV58726877; called by muse, mutect2, varscan2
- H2AC17 | c.180T>C p.T60= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100377444, COSV58153456; called by muse, mutect2
- KCNH8 | c.2760G>A p.E920= | Silent (SNP) | VAF 56/292 reads (19%) | catalogued as COSV60480122; called by muse, varscan2
- LAMA1 | c.4017A>T p.S1339= | Silent (SNP) | VAF 33/179 reads (18%) | catalogued as COSV67545681; called by muse, mutect2, varscan2
- MAGEC1 | c.2490T>A p.P830= | Silent (SNP) | VAF 113/846 reads (13%) | catalogued as COSV53583089; called by muse, mutect2, varscan2
- NAV3 | c.3030C>T p.L1010= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as COSV57118609; called by muse, mutect2, varscan2
- NBPF26 | c.1914G>A p.E638= (on ENST00000620612; = p.E376= on NM_001351372.1) | Silent (SNP) | VAF 24/512 reads (5%) | called by muse, mutect2
- OR10G4 | c.9C>T p.N3= | Silent (SNP) | VAF 30/316 reads (9%) | catalogued as rs547870, COSV57978291; called by muse, mutect2
- OR52L1 | c.126G>A p.Q42= | Silent (SNP) | VAF 16/183 reads (9%) | catalogued as COSV59986890; called by muse, mutect2
- PCDHB2 | c.1305C>T p.T435= | Silent (SNP) | VAF 72/301 reads (24%) | catalogued as COSV50565028, COSV50631636; called by muse, mutect2, varscan2
- POTEE | c.1978C>T p.L660= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV58247723; called by muse, mutect2, varscan2
- POU3F4 | c.519C>T p.G173= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV64540755; called by muse, mutect2, varscan2
- SNW1 | c.1422C>T p.P474= | Silent (SNP) | VAF 116/788 reads (15%) | catalogued as rs757411345, COSV53175168; called by muse, mutect2, varscan2
- SYNE1 | c.4908C>T p.Y1636= (on ENST00000367255 / NM_182961.4; = p.Y1643= on NM_033071.3) | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as rs771955377, COSV55076384; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- SYP | c.108C>T p.F36= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs782820659, COSV54295006; called by muse, mutect2, varscan2
- TECPR2 | c.2427C>A p.P809= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV63972511; called by muse, mutect2, varscan2
- TRIM45 | c.561G>A p.K187= | Silent (SNP) | VAF 47/296 reads (16%) | catalogued as COSV56715250; called by muse, mutect2, varscan2
- TSHZ3 | c.1359G>A p.T453= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as rs774108841, COSV53668811; called by muse, mutect2, varscan2
- ZNF532 | c.3723G>A p.G1241= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV60176370; called by muse, mutect2
- AL662899.2 | c.367+311A>T | Intron (SNP) | VAF 20/149 reads (13%) | catalogued as COSV65508317; called by muse, mutect2, varscan2
- LHX9 | chr1:197912546 C>A | 5'Flank (SNP) | VAF 41/174 reads (24%) | catalogued as COSV100435586, COSV61328569; called by muse, varscan2
